Somatic mutation profile of tumor specimen TCGA-L5-A8NK-01A (aliquot TCGA-L5-A8NK-01A-21D-A37C-09) from TCGA case TCGA-L5-A8NK, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 84.1 years (30,719 days).
Specimen TCGA-L5-A8NK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe537c8f-d1db-46d6-b8e8-ea2f4accfa3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NK-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NK-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a564e8-50d4-49b7-b7eb-0e34b6a6c3ec

The open-access MAF lists 197 somatic variants for this specimen: 145 protein-altering or splice-affecting, 46 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 46, Nonsense Mutation 11, Frame Shift Del 5, RNA 4, Intron 1, Splice Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs1484689392, CM011258, CM086758, COSV56855035; called by muse, mutect2
- AC093827.5 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55744570, COSV99892884; called by muse, mutect2, varscan2
- ALKBH3 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs1279859258, COSV100236156; called by muse, mutect2, varscan2
- AMBN | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as rs745938371; called by muse, mutect2, varscan2
- BCAS3 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs868630556, COSV66770009; called by muse, mutect2
- CACNA1C | c.5080G>A p.D1694N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV59750141; called by muse, mutect2, varscan2
- CACNG8 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.963); catalogued as rs750396252, COSV54415420, COSV99555140; called by muse, mutect2, varscan2
- CDK12 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV71001352, COSV71001754, COSV71002334; called by muse, mutect2, varscan2
- CFHR2 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs776884192; called by muse, mutect2, varscan2
- CLUH | c.3083G>A p.R1028H (on ENST00000435359; = p.R1067H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777344374; called by muse, mutect2
- COL23A1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779240932; called by muse, mutect2, varscan2
- CTNNA2 | c.2792G>A p.R931Q (on ENST00000402739 / NM_001282597.3; = p.R883Q on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs529691509, COSV58137727, COSV58160707; called by muse, mutect2
- DIDO1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs770549757, COSV56623373, COSV56627673; called by muse, mutect2
- DTNA | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs200021359, COSV52003014; called by muse, mutect2, varscan2
- DZIP1L | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747572718; called by muse, mutect2, varscan2
- ELOA2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.901); catalogued as rs955368469, COSV55305056; called by muse, mutect2, varscan2
- EMILIN2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs115304890; called by muse, mutect2, varscan2
- F2RL3 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs200284465; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FLII | c.3277G>C p.E1093Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs760884592; called by muse, mutect2
- GLI2 | c.3353C>G p.S1118C (on ENST00000361492 / NM_001374353.1; = p.S1135C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs140601980; called by muse, mutect2, varscan2
- GPR32 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV54513740; called by muse, mutect2
- H1-5 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); catalogued as rs776470457; called by muse, mutect2, varscan2
- HDX | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52984393; called by muse, mutect2, varscan2
- HMGN4 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs146576097; called by muse, mutect2, varscan2
- HS6ST1 | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs752189949; called by muse, varscan2
- IFIH1 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV55126253, COSV55127391; called by muse, mutect2, varscan2
- IMPG1 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.104); catalogued as COSV64056206; called by muse, mutect2, varscan2
- ITPR2 | c.6520C>G p.R2174G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs144805961; called by muse, mutect2, varscan2
- KCNJ11 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1282255458; called by muse, mutect2
- KCNMB3 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.055); catalogued as rs1332110656; called by muse, mutect2, varscan2
- KIF20B | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765780636; called by muse, mutect2, varscan2
- KMT2C | c.8579C>G p.S2860* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV51424335; called by muse, mutect2, varscan2
- KRI1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV57264080; called by muse, mutect2, varscan2
- LARGE1 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs200603479, COSV100505111; called by muse, mutect2, varscan2
- MAN2C1 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51231953; called by muse, mutect2, varscan2
- MGA | c.5931del p.D1979Mfs*6 (on ENST00000219905 / NM_001164273.1; = p.D1770Mfs*6 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV54958031; called by pindel, varscan2
- MGA | c.6103G>C p.E2035Q (on ENST00000219905 / NM_001164273.1; = p.E1826Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV54951514; called by muse, mutect2, varscan2
- MKI67 | c.6482G>A p.R2161K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1167713449; called by muse, mutect2, varscan2
- MMP14 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs17884647; called by muse, mutect2, varscan2
- NEUROD4 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409059582, COSV54473637; called by muse, mutect2, varscan2
- NOC4L | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs1438121825; called by muse, mutect2, varscan2
- OR4D9 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV61434753; called by muse, mutect2, varscan2
- OR4K14 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs745737183; called by muse, mutect2, varscan2
- OR51A7 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs753338342, COSV63788015; called by muse, mutect2, varscan2
- PAH | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs886042068, CM1511449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARD3 | c.1708-1G>C p.X570_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | catalogued as COSV60761483; called by muse, mutect2
- PCDH10 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.767); catalogued as COSV52092097, COSV99994360; called by muse, mutect2, varscan2
- PCDHA7 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782011323, COSV65348019; called by muse, mutect2, varscan2
- PRB2 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV101231380; called by muse, varscan2
- PRRG3 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.424); catalogued as rs143276868, COSV64850864; called by muse, mutect2, varscan2
- PTK7 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.81); catalogued as COSV57850623; called by muse, mutect2, varscan2
- PTPRT | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV61958362; called by muse, mutect2, varscan2
- RASSF10 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375043143; called by muse, mutect2, varscan2
- RNF168 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV58839365; called by muse, mutect2, varscan2
- RPTN | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs949794539; called by muse, mutect2, varscan2
- SLC7A9 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1287819836; called by muse, mutect2
- SMG6 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs748739928, COSV53977634; called by muse, mutect2, varscan2
- TAPBP | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs374308480; called by muse, mutect2, varscan2
- TEX55 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs1399473213, COSV55210903; called by muse, mutect2, varscan2
- TLN1 | c.6704G>A p.R2235Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs752190315; called by muse, mutect2, varscan2
- TNFRSF8 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs148756853; called by muse, mutect2, varscan2
- TUBGCP2 | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs561848773; called by muse, mutect2, varscan2
- WFS1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs138682654, CM033824; ClinVar: uncertain significance; called by muse, varscan2
- ZNF358 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV51177704, COSV99900360; called by muse, mutect2, varscan2
- ABI3 | c.735_743del p.P246_A248del | In Frame Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- AJUBA | c.791_792del p.V264Dfs*41 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2
- ALLC | c.535G>T p.V179L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ANXA5 | c.404C>G p.S135* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- ATXN2 | c.1178C>G p.S393C (on ENST00000550104; = p.S233C on NM_002973.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- B3GNT7 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- BMP6 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- BNIP5 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BUB1 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- C2CD2 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CACYBP | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC151 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CEP95 | c.1360C>G p.P454A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- CFH | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- CPNE8 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- CSMD3 | c.2764G>A p.E922K (on ENST00000297405 / NM_001363185.1; = p.E818K on NM_052900.3) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSTF2 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DAP3 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DCAF16 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EFCAB13 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM155A | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FLII | c.2857G>C p.E953Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.051); called by muse, mutect2
- GNAS | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GOLGA3 | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, varscan2
- GOLGA3 | c.2619G>T p.R873S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, varscan2
- GPHN | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GRIK2 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H3C6 | c.114del p.K38Nfs*25 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- HSPA8 | c.1783C>G p.Q595E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ICE2 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ILK | c.1344G>C p.K448N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- IQGAP3 | c.2904C>G p.I968M | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.188); called by muse, mutect2
- KDM1B | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- KIAA0319L | c.1871C>G p.S624* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- MAST2 | c.3702G>C p.K1234N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MGA | c.5292G>C p.L1764F (on ENST00000219905 / NM_001164273.1; = p.L1555F on NM_001080541.2) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGA | c.5780G>C p.G1927A (on ENST00000219905 / NM_001164273.1; = p.G1718A on NM_001080541.2) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGA | c.6518G>T p.R2173I (on ENST00000219905 / NM_001164273.1; = p.R1964I on NM_001080541.2) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); called by muse, varscan2
- MGAT4A | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- MORC3 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.5437A>C p.T1813P | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NAA25 | c.898del p.E300Kfs*4 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- NAB2 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- NBEA | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NIBAN1 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NLRP1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.834); called by muse, mutect2
- NUP210L | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OBSL1 | c.2359G>C p.E787Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PAX4 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHAC2 | c.1042C>G p.H348D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- PIGO | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIKFYVE | c.4278del p.I1427Lfs*8 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- PRKRIP1 | c.488G>C p.S163T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); called by muse, mutect2
- PRKRIP1 | c.490A>C p.S164R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.386); called by muse, mutect2
- RBKS | c.503G>C p.R168P | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RBM19 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIPK2 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ROCK2 | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RP2 | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC30A2 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SLCO1C1 | c.1880G>C p.R627T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- SMARCAD1 | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SNRNP200 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- STAM | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D22A | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TCOF1 | c.1984G>T p.G662C (on ENST00000377797 / NM_001135243.1; = p.G585C on NM_000356.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TIMM23 | c.300G>C p.L100F | Missense Mutation (SNP) | VAF 31/351 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- TMED10 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, varscan2
- TMEM117 | c.1056G>C p.L352F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM49 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, varscan2
- TSGA10 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTN | c.81685G>C p.E27229Q (on ENST00000591111; = p.E19805Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- UBR3 | c.4276A>G p.I1426V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS13B | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS8 | c.3641T>A p.M1214K (on ENST00000625842 / NM_001349294.1; = p.M1212K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- XRRA1 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZBTB17 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZNF776 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG4 | c.528G>A p.V176= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- ADAMTS12 | c.1734G>A p.G578= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2
- CBX8 | c.87C>G p.L29= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- CCDC91 | c.630C>T p.L210= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs758479417; called by muse, mutect2, varscan2
- CFAP100 | c.1011G>C p.R337= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- CHD7 | c.8508G>T p.P2836= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- CLNK | c.1230G>A p.R410= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs762843460, COSV57014061; called by muse, mutect2, varscan2
- CNTN4 | c.1617G>C p.L539= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- CSPG4 | c.1560G>A p.L520= | Silent (SNP) | VAF 85/210 reads (40%) | called by muse, mutect2, varscan2
- CYRIA | c.21C>G p.V7= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- FAT4 | c.4566C>A p.L1522= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- FLT3 | c.564C>T p.S188= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs774682624, COSV54068526, COSV99610282; called by muse, mutect2, varscan2
- FOXK1 | c.1869C>T p.T623= | Silent (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- FPR2 | c.789G>T p.L263= | Silent (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- FZD9 | c.1122G>C p.L374= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- GNB2 | c.933C>T p.H311= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs755263504, COSV51939471; called by muse, mutect2, varscan2
- GPT2 | c.678C>T p.L226= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs761253609; called by muse, mutect2, varscan2
- HAL | c.915C>G p.L305= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- HERC2 | c.2577C>T p.S859= | Silent (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- KNDC1 | c.4125C>T p.A1375= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs138202794; called by muse, varscan2
- KPRP | c.243G>A p.V81= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1557827210; called by muse, mutect2, varscan2
- LRP2 | c.10557C>T p.C3519= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs113268518; called by muse, mutect2, varscan2
- MAST4 | c.6489G>A p.P2163= (on ENST00000403625 / NM_001164664.2; = p.P1974= on NM_015183.3) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs750408242, COSV99844049; called by muse, mutect2, varscan2
- MGA | c.6582G>A p.K2194= (on ENST00000219905 / NM_001164273.1; = p.K1985= on NM_001080541.2) | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- MRPS11 | c.387G>A p.Q129= | Silent (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- MTMR11 | c.1332C>T p.L444= (on ENST00000439741 / NM_001145862.2; = p.L372= on NM_181873.3) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs782240807; called by muse, mutect2, varscan2
- OR5AU1 | c.831C>A p.I277= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV58615883; called by muse, mutect2, varscan2
- PABPC1 | c.120C>A p.I40= | Silent (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- PARD3 | c.4020G>A p.A1340= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs533880946, COSV100631306, COSV61060272; called by muse, mutect2, varscan2
- PBX1 | c.1032A>T p.G344= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- PDE5A | c.366G>A p.V122= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV53351259; called by muse, mutect2, varscan2
- PHKA2 | c.2088G>A p.T696= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs151240321; called by muse, mutect2, varscan2
- POLE | c.4653C>T p.H1551= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV57674210; called by muse, mutect2, varscan2
- POLG | c.3261T>A p.A1087= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- PTPRN | c.1545C>G p.T515= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- PURA | c.837G>A p.K279= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- RANBP3 | c.1284C>G p.L428= (on ENST00000340578 / NM_007322.3; = p.L423= on NM_003624.3) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs774907276; called by muse, mutect2, varscan2
- RGS4 | c.90T>A p.S30= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- SCN4A | c.2265C>T p.F755= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- SESTD1 | c.396G>A p.L132= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- SH3TC1 | c.144C>T p.P48= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs765366188; called by muse, mutect2
- SYAP1 | c.462T>A p.P154= | Silent (SNP) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- TMCO4 | c.339G>A p.P113= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs767233859, COSV104398013; called by muse, mutect2, varscan2
- VKORC1 | c.258C>T p.I86= | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- ZFAT | c.1173C>T p.L391= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- ZNF540 | c.555G>A p.V185= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100329678; called by muse, mutect2, varscan2
- BTN2A3P | n.106G>A | RNA (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- DCHS2 | n.8355G>A | RNA (SNP) | VAF 11/20 reads (55%) | catalogued as rs375321525, COSV100602796; called by muse, mutect2, varscan2
- DCHS2 | n.5051C>T | RNA (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- DCHS2 | n.1725A>T | RNA (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10361-4023A>G | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV60411278; called by mutect2, varscan2
- VMP1 | c.*1370C>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
